Somatic mutation profile of cancer-model specimen HCM-BROD-0016-C25-85A (3D Organoid, passage 11; aliquot HCM-BROD-0016-C25-85A-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0016-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 66.4 years (24,261 days).
Specimen HCM-BROD-0016-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f60fb400-af23-4400-b13a-261ea524c04a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0016-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0016-C25-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec46b09c-8a3a-4116-b87b-cc276fa209dc

The open-access MAF lists 95 somatic variants for this specimen: 64 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Splice Site 2, Intron 2, Nonsense Mutation 2, Frame Shift Del 1, 5'UTR 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.2152C>T p.R718W (on ENST00000490131; = p.R795W on NM_000388.4) | Missense Mutation (SNP) | VAF 88/501 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909258, CD076766, CM930079; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 220/338 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 232/234 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684573, COSV61686129, COSV61697475; called by mutect2, varscan2
- BEND2 | c.2366C>A p.P789Q | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV66221144; called by muse, mutect2
- BIN3 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 36/655 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs778507963, COSV52385035; called by muse, mutect2
- COL9A2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 194/751 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs868507976; called by muse, mutect2, varscan2
- DEFB116 | c.200G>A p.C67Y | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1451532510, COSV68722176; called by muse, mutect2, varscan2
- ERC2 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 169/425 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs775270120, COSV55604163; called by muse, mutect2, varscan2
- FAM236C | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 254/527 reads (48%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1364780861; called by muse, mutect2, varscan2
- HYDIN | c.4958C>T p.T1653M | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1467915893; called by muse, mutect2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 200/514 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2
- MMRN1 | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs762040114, COSV53333666, COSV53339194; called by muse, mutect2, varscan2
- MTHFD2L | c.388G>A p.V130I (on ENST00000395759 / NM_001144978.2; = p.V72I on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 242/294 reads (82%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs201351553, COSV57470758; called by muse, mutect2, varscan2
- MYO1A | c.1883G>A p.R628H | Missense Mutation (SNP) | VAF 54/626 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762893043; called by muse, mutect2
- NACAD | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 454/786 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs553278532, COSV71989432; called by muse, mutect2, varscan2
- NEFM | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 51/718 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.272); catalogued as COSV55332332; called by muse, mutect2
- NPAT | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 242/544 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV99586185; called by muse, mutect2
- NRG3 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 50/718 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64547677, COSV64586620; called by muse, mutect2
- OR8G5 | c.735C>G p.I245M | Missense Mutation (SNP) | VAF 18/548 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.527); catalogued as COSV58380490; called by muse, mutect2
- PBK | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 117/234 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV100107416; called by muse, mutect2, varscan2
- PDYN | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 188/312 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1028619685; called by muse, mutect2, varscan2
- SALL1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as rs754218708; called by muse, mutect2, varscan2
- TBC1D32 | c.2136T>A p.N712K | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV99251334; called by muse, mutect2
- TENM2 | c.5698C>T p.R1900C (on ENST00000518659 / NM_001122679.2; = p.R1661C on NM_001080428.3) | Missense Mutation (SNP) | VAF 324/607 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs781259756, COSV69124941; called by muse, mutect2, varscan2
- THSD7B | c.4498G>T p.E1500* (on ENST00000272643; = p.E1498* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 35/431 reads (8%) | catalogued as COSV55659710; called by muse, mutect2
- TTC34 | c.1984C>T p.R662W | Missense Mutation (SNP) | VAF 1195/1197 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as rs1048739252, COSV69003576; called by muse, mutect2, varscan2
- UBR1 | c.4264G>T p.V1422F | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99317521; called by mutect2, varscan2
- UCP1 | c.771A>T p.K257N | Missense Mutation (SNP) | VAF 217/260 reads (83%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as CM973746; called by muse, mutect2, varscan2
- ABCC8 | c.1261G>T p.V421F | Missense Mutation (SNP) | VAF 26/486 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2
- APBA2 | c.2175_2178+30del p.X725_splice | Splice Site (DEL) | VAF 221/408 reads (54%) | called by mutect2, pindel, varscan2
- ATL1 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- CLSTN2 | c.1780C>A p.P594T | Missense Mutation (SNP) | VAF 84/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNND1 | c.1681A>C p.I561L | Missense Mutation (SNP) | VAF 187/315 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ENOSF1 | c.713A>G p.Y238C (on ENST00000340116 / NM_001354066.2; = p.Y190C on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/504 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2
- ILK | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 236/240 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- KRTAP13-1 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); called by muse, mutect2
- MARCHF11 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 65/1075 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- MINK1 | c.1946G>A p.G649D | Missense Mutation (SNP) | VAF 52/575 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- MOB2 | c.545_546del p.F182Cfs*? | Frame Shift Del (DEL) | VAF 466/632 reads (74%) | called by mutect2, pindel, varscan2
- MORF4L1 | c.643A>G p.T215A (on ENST00000331268 / NM_206839.2; = p.T176A on NM_006791.4) | Missense Mutation (SNP) | VAF 41/274 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MRTFB | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 166/337 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MYO3A | c.2806G>C p.D936H | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO3B | c.1459G>T p.D487Y | Missense Mutation (SNP) | VAF 18/679 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- NRG1 | c.1790C>A p.A597D (on ENST00000405005 / NM_013964.5; = p.A602D on NM_013956.5) | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- OPHN1 | c.1355A>T p.Y452F | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- PADI1 | c.93-1G>C p.X31_splice | Splice Site (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- PCDH17 | c.221T>A p.L74Q | Missense Mutation (SNP) | VAF 64/747 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRPF8 | c.1549C>T p.H517Y | Missense Mutation (SNP) | VAF 68/486 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RASGRP3 | c.785A>T p.H262L | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SDK1 | c.1855T>A p.S619T | Missense Mutation (SNP) | VAF 51/562 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.047); called by muse, mutect2
- SEC23IP | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.057); called by muse, mutect2
- SEMA6C | c.1420T>C p.Y474H | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC36A4 | c.1443A>C p.K481N | Missense Mutation (SNP) | VAF 135/285 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPATA4 | c.405T>A p.H135Q | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TFEC | c.193A>T p.I65F | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- TJP1 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TP53 | c.541_542insCCTGCT p.R181delinsPCC | In Frame Ins (INS) | VAF 220/237 reads (93%) | called by mutect2, pindel, varscan2
- TTC6 | c.736G>A p.A246T (on ENST00000267368; = p.A1612T on NM_001310135.3) | Missense Mutation (SNP) | VAF 30/620 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- TTN | c.83135G>T p.S27712I (on ENST00000591111; = p.S20288I on NM_003319.4) | Missense Mutation (SNP) | VAF 29/591 reads (5%) | PolyPhen benign (0.106); called by muse, mutect2
- TTN | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 282/529 reads (53%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR17 | c.3934C>A p.P1312T | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XIRP1 | c.4126G>A p.V1376I | Missense Mutation (SNP) | VAF 62/679 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- ZAR1L | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 142/209 reads (68%) | called by muse, mutect2, varscan2
- ZNF226 | c.663A>T p.E221D | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ACSM5 | c.1599G>A p.T533= | Silent (SNP) | VAF 121/362 reads (33%) | catalogued as rs367777662; called by muse, mutect2, varscan2
- CALHM5 | c.741A>G p.E247= | Silent (SNP) | VAF 35/523 reads (7%) | called by muse, mutect2
- CEP112 | c.1149A>G p.E383= | Silent (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- CETP | c.81C>A p.G27= | Silent (SNP) | VAF 46/355 reads (13%) | called by muse, mutect2, varscan2
- CYP7B1 | c.1323G>A p.P441= | Silent (SNP) | VAF 209/408 reads (51%) | catalogued as rs201281307, COSV100042659; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DNAH6 | c.4848A>G p.E1616= | Silent (SNP) | VAF 32/309 reads (10%) | called by muse, mutect2, varscan2
- DRD5 | c.15C>A p.G5= | Silent (SNP) | VAF 51/324 reads (16%) | called by mutect2, varscan2
- FKBP5 | c.234C>G p.V78= | Silent (SNP) | VAF 32/287 reads (11%) | called by muse, mutect2, varscan2
- GCN1 | c.3501C>T p.D1167= | Silent (SNP) | VAF 30/560 reads (5%) | catalogued as rs201407740; called by muse, mutect2
- HOXB3 | c.831C>T p.N277= | Silent (SNP) | VAF 440/440 reads (100%) | catalogued as rs1464006754, COSV100290687; called by muse, mutect2, varscan2
- ILK | c.933A>C p.L311= | Silent (SNP) | VAF 234/238 reads (98%) | called by mutect2, varscan2
- INPP4B | c.1092C>T p.I364= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV53734413; called by muse, mutect2
- KHDRBS3 | c.921A>G p.G307= | Silent (SNP) | VAF 14/524 reads (3%) | called by muse, mutect2
- LEFTY1 | c.162C>T p.P54= | Silent (SNP) | VAF 59/690 reads (9%) | called by muse, mutect2
- NLRP7 | c.2202G>A p.T734= (on ENST00000340844 / NM_206828.3; = p.T706= on NM_139176.3) | Silent (SNP) | VAF 250/501 reads (50%) | catalogued as rs141917868; called by muse, mutect2, varscan2
- PLEKHG4B | c.2220G>A p.R740= (on ENST00000283426; = p.R1096= on NM_052909.5) | Silent (SNP) | VAF 74/740 reads (10%) | called by muse, mutect2, varscan2
- RAD51B | c.543G>A p.R181= | Silent (SNP) | VAF 20/332 reads (6%) | called by muse, mutect2
- RGPD3 | c.4983C>G p.S1661= | Silent (SNP) | VAF 44/741 reads (6%) | called by muse, mutect2
- RIMBP2 | c.429C>T p.S143= | Silent (SNP) | VAF 155/488 reads (32%) | catalogued as rs765478893, COSV55469143; called by muse, mutect2, varscan2
- RNF216 | c.1719G>T p.L573= (on ENST00000425013 / NM_207116.3; = p.L630= on NM_207111.4) | Silent (SNP) | VAF 46/589 reads (8%) | catalogued as COSV104433174; called by muse, mutect2
- SEZ6L | c.1104C>T p.S368= | Silent (SNP) | VAF 40/444 reads (9%) | catalogued as rs565841729, COSV50666341; called by muse, mutect2
- SLC49A3 | c.858C>T p.L286= (on ENST00000404286 / NM_001294341.2; = p.L285= on NM_032219.4) | Silent (SNP) | VAF 27/402 reads (7%) | called by muse, mutect2
- TBKBP1 | c.771G>A p.L257= | Silent (SNP) | VAF 515/516 reads (100%) | called by muse, mutect2, varscan2
- TSHZ3 | c.720C>T p.R240= | Silent (SNP) | VAF 129/370 reads (35%) | catalogued as rs760381593; called by muse, mutect2, varscan2
- TTC21B | c.3228A>T p.G1076= | Silent (SNP) | VAF 33/560 reads (6%) | called by muse, mutect2
- UBE2E2 | c.345G>A p.P115= | Silent (SNP) | VAF 27/403 reads (7%) | catalogued as rs779913284, COSV59975446; called by muse, mutect2
- UNC80 | c.3921C>T p.Y1307= | Silent (SNP) | VAF 77/502 reads (15%) | catalogued as rs1040212766; called by muse, mutect2, varscan2
- KCNA4 | c.-1155G>A | 5'UTR (SNP) | VAF 29/404 reads (7%) | called by muse, mutect2
- MRO | c.*1G>A | 3'UTR (SNP) | VAF 171/171 reads (100%) | called by muse, mutect2, varscan2
- NFASC | c.2470+2094C>T | Intron (SNP) | VAF 285/398 reads (72%) | catalogued as rs776451525; called by muse, varscan2
- TRIM9 | c.1604-3861A>G | Intron (SNP) | VAF 200/367 reads (54%) | called by muse, mutect2, varscan2
